Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6677, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6677-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
Colon carcinoma.

Specimens Submitted:
1: Terminal ileum, appendix, and ascending colon; Resection

DIAGNOSIS:
1. Terminal ileum, appendix, and ascending colon; Resection:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Hepatic flexure
Tumor Size:
Length is 3.5 cm
Width is 8 cm
Maximal thickness is 0.6 cm
Tumor Budding:
Absent
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Not identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Not identified
Surgical Margins:
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Tubular adenoma; number: 2
Non-Neoplastic Bowel:
Unremarkable

** Continued on next page **

[page 2 of 3]
Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 20

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1. The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 15.2 cm in length and 4.1 cm in circumference at the proximal resected margin. The remaining colon measures 41.6 in length with a circumference of 8.2 cm at the distal resected margin. The attached appendix measures 9 cm in length and averages 0.8 cm in diameter. The appendiceal and intestinal serosa are pink tan and smooth. The colonic serosa has a focus of retraction and is inked black. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 6 cm in thickness. There is also omentum (17.2 to 15 x 1 cm) which is serially sectioned revealing unremarkable adipose tissue. The specimen is opened to reveal a circumferential tan-pink mass measuring 3.5 cm in length and 8 cm in width. The mass is located in the transverse colon, immediately adjacent to a tattoo site, 32.2 cm from the proximal margin, 10.3 cm from the distal margin, and 16.5 cm from the ileocecal valve. Sectioning shows that the tumor invades the muscularis. The depth of invasion is 0.3 cm grossly; the tumor has a thickness of 0.6 centimeters. There are two tan-pink polypoidal masses (1.1 cm and 0.4 cm in greatest dimension) located 3.0 cm and 4.5 cm from ileocecal valve, respectively. The remaining mucosa is unremarkable. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for

Summary of sections:

P - proximal margin shave

D - distal margin shave

T tumor

** Continued on next page **

[page 3 of 3]
P-polypoid masses
RS -representative sections
A appendix, representative sections
LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:
Part 1: Terminal ileum, appendix, and ascending colon; Resection

Block	Sect. Site	PCs
1	A	1
5	BLN	10
1	DM	1
8	LN	24
1	P	1
1	PM	1
1	RS	1
5	T	5

Source: NCI Genomic Data Commons file b839f54c-1dc5-42fa-9550-3b4f2ca80323 (TCGA-CM-6677.35F4EA93-223A-46F7-A6A9-BC69646B313B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).